Gene-level copy-number profile of tumor specimen TCGA-AG-3893-01A from TCGA case TCGA-AG-3893, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.7 years (27,272 days).
Specimen TCGA-AG-3893-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.4d18a0e8-8a97-4e20-adf9-516455dbc992.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3893-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe207b29-f09c-4f84-9919-dbd4fe988a30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 6,962; copy number 2: 41,618; copy number 3: 7,635; copy number 4: 731; copy number 5: 2,745; copy number 6: 98; copy number 7: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3893-01A-01D-1428-01): tumor purity 0.72, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,703,883–6,721,960, 2 genes: AC007012.2, AC007012.1.
- chr18:50,457,887–51,283,896, 15 genes: RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,855 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:18,807,993–41,779,388, 429 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–738,106, 19 genes, copy number 6: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–893,112, 2 genes, copy number 6: AC100797.4, AC026950.2.
- chr8:35,862,123–40,897,833, 106 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr18:76,173,304–76,498,088, 12 genes, copy number 5: AC103808.6, LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516, AC009716.1, AC009716.2, AC018413.1, ZNF516-DT.
- chr20:30,294,550–64,313,132, 896 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
